Somatic mutation profile of tumor specimen MP2PRT-PAUBFD-TMP1-A (aliquot MP2PRT-PAUBFD-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PAUBFD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,826 days).
Specimen MP2PRT-PAUBFD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83a95e57-31c6-4e11-b7e0-3f399c35a203.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBFD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBFD-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9bfe9e4-9eb9-4e5f-896f-f0032467d16b

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Intron 2, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 58/410 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- JAK2 | c.2049A>C p.R683S | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519723, COSV67569539, COSV67577012; ClinVar: pathogenic; called by muse, varscan2
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDKN2AIP | c.350_352del p.T117del | In Frame Del (DEL) | VAF 190/412 reads (46%) | catalogued as rs753566867; called by pindel, varscan2
- COL16A1 | c.2812C>A p.L938I | Missense Mutation (SNP) | VAF 194/430 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.096); catalogued as rs750147456; called by muse, mutect2, varscan2
- ESX1 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 46/1687 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV101006520, COSV65425378; called by muse, mutect2
- FAM131B | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 206/450 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as rs368171076; called by muse, mutect2, varscan2
- FOXB2 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 46/955 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as rs1308575447; called by muse, mutect2
- IGSF1 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 44/1449 reads (3%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.494); catalogued as rs1026938508; called by muse, mutect2
- KLRG2 | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 35/530 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); catalogued as COSV61801761; called by muse, mutect2
- L1CAM | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 73/1103 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1434074663; called by muse, mutect2
- NHS | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 36/956 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs369653594; called by muse, mutect2
- RPS7 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 36/650 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs61740528; called by muse, mutect2
- STRA6 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 36/626 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs144043304; ClinVar: uncertain significance; called by muse, mutect2
- THBS4 | c.1571T>G p.V524G | Missense Mutation (SNP) | VAF 17/325 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.357); catalogued as COSV100644358; called by muse, mutect2
- TRPC5 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 561/853 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747130444, COSV53286728; called by muse, mutect2, varscan2
- ZNF532 | c.3638C>T p.T1213M | Missense Mutation (SNP) | VAF 71/520 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1173697479; called by muse, mutect2, varscan2
- C3orf20 | c.1417C>A p.L473I | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); called by muse, mutect2
- FSD1 | c.806T>C p.M269T | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR101 | c.890G>T p.S297I | Missense Mutation (SNP) | VAF 46/1330 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2
- LCOR | c.2839G>T p.E947* | Nonsense Mutation (SNP) | VAF 169/354 reads (48%) | called by muse, mutect2, varscan2
- LIMD1 | c.116_117dup p.E40Pfs*59 | Frame Shift Ins (INS) | VAF 150/464 reads (32%) | called by pindel, varscan2
- PTPRG | c.2971G>A p.V991I | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- RTL9 | c.1925C>A p.T642K | Missense Mutation (SNP) | VAF 272/905 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ACOT11 | c.981C>T p.D327= | Silent (SNP) | VAF 271/594 reads (46%) | catalogued as rs753971284; called by muse, mutect2, varscan2
- APBA2 | c.24C>T p.S8= | Silent (SNP) | VAF 251/525 reads (48%) | catalogued as rs770399185, COSV68790732; called by muse, mutect2, varscan2
- B3GAT1 | c.141G>A p.T47= | Silent (SNP) | VAF 40/754 reads (5%) | catalogued as rs374540626; called by muse, mutect2
- KCNG3 | c.156C>T p.D52= | Silent (SNP) | VAF 289/572 reads (51%) | called by muse, mutect2, varscan2
- KCTD4 | c.303C>G p.P101= | Silent (SNP) | VAF 197/439 reads (45%) | called by muse, mutect2, varscan2
- LAMA1 | c.8235G>A p.T2745= | Silent (SNP) | VAF 181/394 reads (46%) | catalogued as rs139987349; called by muse, mutect2, varscan2
- MAD1L1 | c.1395C>T p.G465= | Silent (SNP) | VAF 219/514 reads (43%) | called by muse, mutect2, varscan2
- PAX2 | c.825C>T p.D275= (on ENST00000428433 / NM_003987.5; = p.D252= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 210/464 reads (45%) | catalogued as rs200804078, COSV100695198; called by muse, mutect2, varscan2
- SLC4A5 | c.1401C>T p.A467= | Silent (SNP) | VAF 50/888 reads (6%) | catalogued as rs139474194; called by muse, mutect2
- DIP2C | c.85+39309G>A | Intron (SNP) | VAF 231/502 reads (46%) | catalogued as rs910337133, COSV55146611; called by muse, mutect2, varscan2
- PTPN13 | c.546+534G>A | Intron (SNP) | VAF 144/340 reads (42%) | called by muse, mutect2, varscan2
